CCDI case PBCITR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/facb6347-29dd-47e1-af37-d423f73211d9

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Dermatofibrosarcoma protuberans, NOS: ICD-O-3 morphology code: 8832/3; Tissue or organ of origin: Skin of trunk; Age at diagnosis: 8.3 years (3,021 days).

Biospecimens (3 samples)
- Sample 0DSYEA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSYEC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSYEQ: Tissue type: Tumor; Specimen type: Solid Tissue.
